Gene-level copy-number profile of tumor specimen TCGA-DD-AAE3-01A from TCGA case TCGA-DD-AAE3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 50.0 years (18,271 days).
Specimen TCGA-DD-AAE3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.920ff897-b6da-4f52-8e44-fcec4d856eb7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAE3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6464b81b-6b21-4d0a-927d-17834f99a836

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,968; copy number 3: 12,197; copy number 4: 20,625; copy number 5: 12,615; copy number 6: 5,031; copy number 7: 275; copy number 8: 5,643; copy number 9: 460.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAE3-01A-11D-A40Q-01): tumor purity 0.7, ploidy 4.54, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 460 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:167,284,799–168,264,157, 1 gene, copy number 9 (within-gene range 8–9): TENM2.
- chr5:167,721,363–181,342,213, 366 genes, copy number 9 (broad region; genes not listed).
- chr13:68,985,058–68,986,064, 1 gene, copy number 9: ZDHHC20P4.
- chr14:21,887,857–22,518,871, 92 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
